Somatic mutation profile of tumor specimen C3N-01270-02 (aliquot CPT0379980009) from CPTAC case C3N-01270, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 66.6 years (24,327 days).
Specimen C3N-01270-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15ba8e66-faea-418a-aacc-c99806cefe8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01270-31 (Blood Derived Normal), aliquot CPT0380060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9689e32a-2e10-4e71-9fbf-5c49004d2b5e

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT1 | c.2843G>A p.W948* | Nonsense Mutation (SNP) | VAF 62/114 reads (54%) | catalogued as rs755629130; called by muse, mutect2, varscan2
- FAT4 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV101272541; called by muse, mutect2, varscan2
- HNRNPUL2 | c.674G>C p.R225P | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV53665062, COSV53665306; called by muse, mutect2, varscan2
- KCTD8 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as rs765990631, COSV63586384; called by muse, mutect2, varscan2
- PLEKHG4B | c.13C>T p.R5W (on ENST00000283426; = p.R361W on NM_052909.5) | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1039069776, COSV52056311; called by muse, mutect2, varscan2
- SELP | c.2069G>C p.G690A | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs756277455; called by muse, mutect2, varscan2
- UGT1A4 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs762367100, COSV100531094, COSV59389879, COSV59396877; called by muse, mutect2
- YTHDC2 | c.1390T>C p.W464R | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as rs1157344082; called by muse, mutect2, varscan2
- DENND6A | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- DOCK6 | c.3983C>T p.T1328I | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- GIGYF2 | c.1040A>C p.E347A | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MAP1A | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTUD1 | c.1360G>T p.V454L | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCM1 | c.3857C>G p.A1286G | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROBO3 | c.3017C>T p.T1006M | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMEM183A | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATRIP | c.612A>C p.T204= | Silent (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- GPR141 | c.90C>T p.G30= | Silent (SNP) | VAF 67/170 reads (39%) | catalogued as rs368456046; called by muse, mutect2, varscan2
- PNMA8B | c.1110C>T p.D370= | Silent (SNP) | VAF 87/215 reads (40%) | catalogued as rs750671772; called by muse, mutect2, varscan2
- HBA2 | c.96-42C>T | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as rs1328255996; called by mutect2, varscan2
